MMRF case MMRF_1232 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ddb370db-7348-49a2-bcb0-5afdefa6d644

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Dead; Days to death: 972 days (2.7 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.9 years (21,518 days); ISS stage: III; Days to last known disease status: 972 days (2.7 years); Days to last follow up: 972 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 86 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 33 days; Days to treatment end: 101 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 109 days; Days to treatment end: 417 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 522 days (1.4 years); Days to treatment end: 560 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 560 days (1.5 years); Days to treatment end: 707 days (1.9 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 560 days (1.5 years); Days to treatment end: 655 days (1.8 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 655 days (1.8 years); Days to treatment end: 707 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 783 days (2.1 years); Days to treatment end: 847 days (2.3 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 847 days (2.3 years); Days to treatment end: 951 days (2.6 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 852 days (2.3 years); Days to treatment end: 951 days (2.6 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 972.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 2.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 109 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.048 mg/dL; Immunoglobulin G 3.66 g/L; Immunoglobulin A 40 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 6.29 µg/mL; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 4.77 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.5 mmol/L; Albumin 33 g/L; Total Protein 9.1 g/dL; Glucose 5.01 mmol/L; C-Reactive Protein 1.75 mg/dL.
- Day 88 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.534 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.045 mg/dL; Immunoglobulin G 4.39 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 4.57 mmol/L.
- Day 186 (ECOG 1): Hemoglobin 7.75 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 5.61 mmol/L.
- Day 242 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.059 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.08 mg/dL; Immunoglobulin G 4.18 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL; Glucose 4.24 mmol/L.
- Day 340 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.689 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.147 mg/dL; Immunoglobulin G 4.73 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 1.94 µg/mL; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.53 mmol/L; Albumin 46 g/L; Total Protein 6.2 g/dL; Glucose 4.57 mmol/L.
- Day 431 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.927 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.765 mg/dL; Immunoglobulin G 8.31 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.48 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 5.23 mmol/L.
- Day 508 (ECOG 0): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.647 mg/dL; Immunoglobulin G 8.23 g/L; Immunoglobulin A 1.84 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 2.51 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 2.75 mmol/L.
- Day 627 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.073 mg/dL; Immunoglobulin G 3.32 g/L; Immunoglobulin A 0.97 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 1.77 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 5.7 g/dL; Glucose 4.29 mmol/L.
- Day 707 (ECOG 1): M Protein 0.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.054 mg/dL; Immunoglobulin G 4.48 g/L; Immunoglobulin A 3.19 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.5 mmol/L; Albumin 45 g/L; Total Protein 7.3 g/dL; Glucose 4.29 mmol/L.
- Day 847 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.461 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.074 mg/dL; Immunoglobulin G 4.15 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.94 mmol/L.

Other clinical attributes
- Day -6: Weight: 76 kg; Height: 164 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1232_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 242 days.
- Sample MMRF_1232_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 847 days (2.3 years).
